Gene-level copy-number profile of tumor specimen TCGA-44-2656-01B from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b6f8ff3d-9a78-461a-b8f9-29ac05a0eea4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-2656-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/2f9ae454-8042-4fe7-a5ce-ba87b387e551

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,405; copy number 2: 57,853; copy number 3: 12; copy number 4: 3.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-2656-01A-02D-A273-01): tumor purity 0.32, ploidy 3.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
